Somatic mutation profile of tumor specimen ALCH-B259-TTP1-A (aliquot ALCH-B259-TTP1-A-1-0-D-A77J-36) from ALCHEMIST case ALCH-B259, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 64.5 years (23,569 days).
Specimen ALCH-B259-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c34e541f-daea-4c77-be2f-68b0f6451d79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B259-NB1-A (Blood Derived Normal), aliquot ALCH-B259-NB1-A-1-0-D-A77J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47a3e998-e752-4e39-b568-8e72b4c2d4b5

The open-access MAF lists 248 somatic variants for this specimen: 158 protein-altering or splice-affecting, 60 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 138, Silent 60, Intron 13, RNA 7, Nonsense Mutation 7, 5'UTR 5, Splice Site 5, Splice Region 4, Frame Shift Del 4, 5'Flank 3, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.959G>T p.R320L | Missense Mutation (SNP) | VAF 45/120 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs1239985410, COSV50260372, COSV50272556, COSV50274400; called by muse, mutect2, varscan2
- RB1 | c.2490-16_2495del p.X830_splice | Splice Site (DEL) | VAF 30/187 reads (16%) | hotspot (GDC flag); called by mutect2, pindel
- TP53 | c.559+1G>A p.X187_splice | Splice Site (SNP) | VAF 158/460 reads (34%) | hotspot (GDC flag); catalogued as rs1131691042, CS137624, COSV52670017, COSV52686439, COSV52695669; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADARB1 | c.880G>T p.A294S | Missense Mutation (SNP) | VAF 90/348 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.09); catalogued as rs1330166367, COSV62343072; called by muse, mutect2, varscan2
- ADCY5 | c.551C>G p.S184C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1401519571; called by muse, mutect2, varscan2
- ADCY8 | c.965T>C p.V322A | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99650675; called by muse, mutect2, varscan2
- AEBP1 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as rs574188983; called by muse, mutect2, varscan2
- APCDD1 | c.299A>G p.N100S | Missense Mutation (SNP) | VAF 131/485 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.279); catalogued as rs1255479618; called by muse, mutect2, varscan2
- ARHGEF6 | c.1672A>G p.K558E | Missense Mutation (SNP) | VAF 151/351 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.405); catalogued as COSV51694689; called by muse, mutect2, varscan2
- ATP9A | c.915G>T p.K305N | Missense Mutation (SNP) | VAF 120/488 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100124362; called by muse, mutect2, varscan2
- CAD | c.4192C>T p.R1398C | Missense Mutation (SNP) | VAF 143/725 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs751579991; called by muse, mutect2, varscan2
- CNBD1 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs890376213; called by muse, mutect2, varscan2
- CRISPLD1 | c.1111G>T p.G371C | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51547300; called by muse, mutect2, varscan2
- DDX1 | c.1592G>T p.G531V | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV51841534; called by muse, mutect2
- DLG1 | c.326G>T p.R109M | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.49); catalogued as COSV100014554; called by muse, mutect2, varscan2
- DLGAP4 | c.716C>A p.P239Q | Missense Mutation (SNP) | VAF 107/407 reads (26%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as COSV100211503; called by muse, mutect2, varscan2
- ETS1 | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 78/277 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as COSV60092535, COSV60093872; called by muse, mutect2, varscan2
- ETV1 | c.1039G>T p.D347Y | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54143241; called by muse, mutect2, varscan2
- FAM135B | c.3463C>A p.L1155I | Missense Mutation (SNP) | VAF 67/292 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52713096; called by muse, mutect2, varscan2
- FRY | c.3643G>T p.D1215Y | Missense Mutation (SNP) | VAF 127/450 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66564453; called by muse, mutect2, varscan2
- FZD3 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 111/381 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as rs1444393038; called by muse, mutect2, varscan2
- GALNT8 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 94/397 reads (24%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs766309626; called by muse, mutect2, varscan2
- HAUS1 | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV99959528; called by muse, varscan2
- HTR3B | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); catalogued as rs770948693; called by muse, mutect2, varscan2
- KIAA1671 | c.4964G>A p.R1655H | Missense Mutation (SNP) | VAF 121/597 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs890567254; called by muse, mutect2, varscan2
- LINGO1 | c.1273C>A p.R425S | Missense Mutation (SNP) | VAF 80/458 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as rs1405011449; called by muse, varscan2
- LRRC40 | c.965A>G p.N322S | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150092881; called by muse, mutect2, varscan2
- LSM11 | c.397G>T p.G133C | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.778); catalogued as rs1247321646; called by muse, mutect2, varscan2
- MAGEB2 | c.113C>A p.A38D | Missense Mutation (SNP) | VAF 126/295 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.422); catalogued as COSV66780518; called by muse, mutect2, varscan2
- MCM9 | c.2392G>T p.G798W | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV60323439; called by muse, mutect2, varscan2
- MYO1B | c.2683A>G p.I895V (on ENST00000304164; = p.I837V on NM_012223.5) | Missense Mutation (SNP) | VAF 57/208 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs753756049; called by muse, mutect2, varscan2
- MYOT | c.112T>C p.S38P | Missense Mutation (SNP) | VAF 263/730 reads (36%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.983); catalogued as rs1189771725; called by muse, mutect2, varscan2
- MZF1 | c.2188G>T p.V730F | Missense Mutation (SNP) | VAF 248/406 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV53042765; called by muse, mutect2, varscan2
- NCAN | c.1349C>T p.T450M | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs1051841821, COSV53059062; called by muse, mutect2, varscan2
- NMI | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 57/416 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs780116282; called by muse, mutect2, varscan2
- OR56A3 | c.178C>A p.H60N | Missense Mutation (SNP) | VAF 102/334 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as COSV100290345; called by muse, mutect2, varscan2
- OR5B3 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 37/153 reads (24%) | catalogued as COSV58677825; called by muse, mutect2, varscan2
- PBXIP1 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 59/473 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as rs747146952; called by muse, mutect2, varscan2
- PCSK2 | c.576C>A p.N192K | Missense Mutation (SNP) | VAF 103/510 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.235); catalogued as COSV52741804; called by muse, mutect2, varscan2
- PFKFB4 | c.1088G>T p.G363V | Missense Mutation (SNP) | VAF 30/111 reads (27%) | PolyPhen probably damaging (1); catalogued as COSV99220118; called by muse, mutect2, varscan2
- PKD1L1 | c.5912C>G p.T1971S | Missense Mutation (SNP) | VAF 142/425 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV56963747; called by muse, mutect2
- POTEE | c.294G>T p.M98I | Missense Mutation (SNP) | VAF 88/429 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1206857910; called by muse, mutect2, varscan2
- POTEJ | c.2197C>A p.P733T | Missense Mutation (SNP) | VAF 109/298 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs1450534915; called by mutect2, varscan2
- PPARD | c.323A>T p.Y108F | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100283225; called by muse, mutect2, varscan2
- RNF148 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 39/261 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as rs777028409; called by muse, mutect2, varscan2
- RNF208 | c.568C>A p.R190S | Missense Mutation (SNP) | VAF 105/384 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as COSV100763166; called by muse, mutect2, varscan2
- SLC16A8 | c.735G>C p.L245F | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as rs758977438; called by muse, mutect2, varscan2
- SPTA1 | c.421del p.D141Tfs*4 | Frame Shift Del (DEL) | VAF 134/927 reads (14%) | catalogued as COSV63760688; called by mutect2, pindel, varscan2
- STAT1 | c.1544A>G p.N515S | Missense Mutation (SNP) | VAF 182/654 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs190269533, COSV63117372; ClinVar: likely benign; called by muse, mutect2, varscan2
- TBCD | c.3289G>T p.E1097* | Nonsense Mutation (SNP) | VAF 107/271 reads (39%) | catalogued as COSV62801964; called by muse, mutect2, varscan2
- THSD7B | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55687904, COSV55747352; called by muse, mutect2, varscan2
- TMEM260 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749064908, COSV55103376; called by muse, mutect2, varscan2
- TMEM74 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 94/375 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs555420346, COSV52463540; called by muse, mutect2, varscan2
- TPTE | c.946G>C p.V316L (on ENST00000618007 / NM_199261.4; = p.V298L on NM_199259.4) | Missense Mutation (SNP) | VAF 62/436 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs764628536; called by muse, varscan2
- UMOD | c.1909C>A p.L637M | Missense Mutation (SNP) | VAF 254/712 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.713); catalogued as COSV100208310; called by muse, mutect2, varscan2
- XRRA1 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 108/479 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as rs748249459, COSV58498152; called by muse, mutect2, varscan2
- ACTRT1 | c.818C>A p.P273Q | Missense Mutation (SNP) | VAF 95/170 reads (56%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- AK7 | c.2068C>G p.P690A | Missense Mutation (SNP) | VAF 181/766 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASCL1 | c.560G>C p.G187A | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- ATP13A2 | c.849G>C p.Q283H | Missense Mutation (SNP) | VAF 114/464 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- BIRC3 | c.756G>C p.M252I | Missense Mutation (SNP) | VAF 72/299 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- BMPR2 | c.1339G>C p.E447Q | Missense Mutation (SNP) | VAF 95/586 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- C5 | c.170A>G p.K57R | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CACNA1F | c.2171A>C p.Y724S | Missense Mutation (SNP) | VAF 69/137 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNA1G | c.4142G>T p.R1381L | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CALHM3 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 98/251 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CDH17 | c.2010C>A p.D670E | Missense Mutation (SNP) | VAF 56/220 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDK13 | c.221C>G p.A74G | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CHIT1 | c.923C>A p.S308Y | Missense Mutation (SNP) | VAF 122/439 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CLSTN1 | c.977G>T p.R326L (on ENST00000377298 / NM_001009566.3; = p.R316L on NM_014944.4) | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.061); called by muse, mutect2
- CNTNAP2 | c.2554+2T>A p.X852_splice | Splice Site (SNP) | VAF 56/467 reads (12%) | called by muse, mutect2, varscan2
- COL6A3 | c.4697C>A p.S1566* | Nonsense Mutation (SNP) | VAF 58/365 reads (16%) | called by muse, mutect2, varscan2
- CSMD1 | c.5335del p.A1779Rfs*49 (on ENST00000520002; = p.A1778Rfs*49 on NM_033225.6) | Frame Shift Del (DEL) | VAF 108/586 reads (18%) | called by mutect2, pindel*, varscan2
- CWF19L2 | c.2085+1del p.X695_splice | Splice Site (DEL) | VAF 50/266 reads (19%) | called by mutect2, pindel, varscan2
- DAB2 | c.1997T>A p.V666E | Missense Mutation (SNP) | VAF 243/1260 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); called by mutect2, varscan2
- DEPDC1 | c.2002G>A p.A668T (on ENST00000456315 / NM_001114120.3; = p.A384T on NM_017779.6) | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- DNAH7 | c.193G>C p.V65L | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- EFCAB1 | c.574A>G p.K192E | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- EPPK1 | c.1907G>T p.R636L | Missense Mutation (SNP) | VAF 78/369 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- ERV3-1 | c.1169G>T p.S390I | Missense Mutation (SNP) | VAF 67/346 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ETS1 | c.433G>T p.V145F | Missense Mutation (SNP) | VAF 54/247 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.027); called by muse, varscan2
- FBN1 | c.7333C>T p.L2445= | Splice Region (SNP) | VAF 102/675 reads (15%) | called by muse, mutect2, varscan2
- FERMT3 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 93/531 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- FEZF2 | c.1280G>T p.C427F | Missense Mutation (SNP) | VAF 194/914 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FKBP6 | c.638T>A p.L213Q | Missense Mutation (SNP) | VAF 173/596 reads (29%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FMO1 | c.88T>C p.C30R | Missense Mutation (SNP) | VAF 141/541 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FREM2 | c.2558A>T p.H853L | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FYN | c.1548G>C p.L516F | Missense Mutation (SNP) | VAF 59/226 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GLI1 | c.2188C>A p.L730M | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GLI2 | c.3301G>T p.G1101C (on ENST00000361492 / NM_001374353.1; = p.G1118C on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 173/568 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- GPR156 | c.2147C>G p.A716G | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- GRIA2 | c.910G>T p.V304F | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- H3-2 | c.133G>T p.G45C | Missense Mutation (SNP) | VAF 128/446 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HECW1 | c.4811G>T p.G1604V | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HELLS | c.2161C>G p.R721G | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPG2 | c.2870A>G p.N957S | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- INHBC | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 120/474 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- IRF6 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 157/517 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITIH5 | c.565G>T p.V189L | Missense Mutation (SNP) | VAF 170/470 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- JAKMIP3 | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- KCNA6 | c.806T>C p.L269P | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2
- KCNH8 | c.2887C>T p.P963S | Missense Mutation (SNP) | VAF 95/384 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- KIDINS220 | c.820A>T p.I274F | Missense Mutation (SNP) | VAF 68/294 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- KRT10 | c.1100A>C p.E367A | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KRTAP19-4 | c.177C>A p.F59L | Missense Mutation (SNP) | VAF 130/625 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- LRRC45 | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 104/257 reads (40%) | called by muse, mutect2, varscan2
- LVRN | c.142C>A p.L48M | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LVRN | c.1031del p.A344Vfs*2 | Frame Shift Del (DEL) | VAF 26/159 reads (16%) | called by pindel, varscan2
- MORC1 | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 82/359 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- MROH2A | c.3092A>G p.Q1031R | Missense Mutation (SNP) | VAF 130/598 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- MUC12 | c.14655C>A p.Y4885* (on ENST00000379442; = p.Y4742* on NM_001164462.1) | Nonsense Mutation (SNP) | VAF 85/292 reads (29%) | called by muse, mutect2, varscan2
- MXRA5 | c.8120G>T p.G2707V | Missense Mutation (SNP) | VAF 154/354 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH1 | c.410C>A p.A137E | Missense Mutation (SNP) | VAF 150/469 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYH11 | c.4579-8G>A | Splice Region (SNP) | VAF 85/195 reads (44%) | called by muse, mutect2, varscan2
- MYT1 | c.2296T>A p.S766T | Missense Mutation (SNP) | VAF 63/335 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NNT | c.2842G>C p.V948L | Missense Mutation (SNP) | VAF 104/636 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- NOVA1 | c.1192T>C p.Y398H | Missense Mutation (SNP) | VAF 37/450 reads (8%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.991); called by muse, mutect2
- NPHP4 | c.790G>T p.V264F | Missense Mutation (SNP) | VAF 93/284 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- NVL | c.1949A>T p.E650V | Missense Mutation (SNP) | VAF 56/492 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- NWD2 | c.3454G>C p.D1152H | Missense Mutation (SNP) | VAF 117/294 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- OLFM4 | c.77del p.G26Dfs*35 | Frame Shift Del (DEL) | VAF 92/362 reads (25%) | called by mutect2, pindel, varscan2
- OR2T6 | c.95G>A p.C32Y | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- OR4A16 | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 105/271 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OSBPL10 | c.520A>G p.M174V | Missense Mutation (SNP) | VAF 110/453 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- OVOL1 | c.509-2A>T p.X170_splice | Splice Site (SNP) | VAF 36/119 reads (30%) | called by muse, mutect2, varscan2
- PATE4 | c.217T>C p.C73R | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- PCSK1N | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- PKD1L1 | c.8422G>T p.D2808Y | Missense Mutation (SNP) | VAF 44/222 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- PKHD1 | c.11171A>G p.Y3724C | Missense Mutation (SNP) | VAF 63/223 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- POTEC | c.1571G>T p.R524L | Missense Mutation (SNP) | VAF 77/371 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- POTEE | c.295G>T p.G99W | Missense Mutation (SNP) | VAF 85/423 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- POTEJ | c.2198C>G p.P733R | Missense Mutation (SNP) | VAF 110/300 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- PSG2 | c.746C>T p.T249I | Missense Mutation (SNP) | VAF 200/435 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- R3HDM1 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RADIL | c.2644G>T p.G882* | Nonsense Mutation (SNP) | VAF 33/91 reads (36%) | called by muse, mutect2
- RAG2 | c.1052C>A p.A351D | Missense Mutation (SNP) | VAF 181/505 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- RASSF5 | c.591A>C p.K197N | Missense Mutation (SNP) | VAF 62/407 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- RPE65 | c.1276T>C p.Y426H | Missense Mutation (SNP) | VAF 95/606 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- RTL9 | c.1642G>T p.A548S | Missense Mutation (SNP) | VAF 169/319 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RTL9 | c.1643C>A p.A548E | Missense Mutation (SNP) | VAF 164/313 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- RXRG | c.307G>A p.V103I | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2
- SGPL1 | c.615+5G>C | Splice Region (SNP) | VAF 36/91 reads (40%) | called by muse, mutect2, varscan2
- SHC2 | c.1679A>G p.Q560R | Missense Mutation (SNP) | VAF 110/307 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC2A5 | c.572-3C>T | Splice Region (SNP) | VAF 119/310 reads (38%) | called by muse, mutect2, varscan2
- SORCS1 | c.1058G>T p.C353F | Missense Mutation (SNP) | VAF 111/349 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPRR3 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 148/782 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.426); called by muse, varscan2
- TECTB | c.899C>A p.S300Y | Missense Mutation (SNP) | VAF 108/350 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENM4 | c.3460A>G p.R1154G | Missense Mutation (SNP) | VAF 54/283 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TMEM63A | c.1513A>G p.K505E | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAJ40 | c.23A>T p.Y8F | Missense Mutation (SNP) | VAF 56/231 reads (24%) | called by muse, mutect2, varscan2
- UNC79 | c.6522C>G p.S2174R (on ENST00000393151 / NM_001346218.2; = p.S1997R on NM_020818.5) | Missense Mutation (SNP) | VAF 61/313 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- UVRAG | c.667A>C p.K223Q | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- VIM | c.760G>T p.V254F | Missense Mutation (SNP) | VAF 212/677 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- WFIKKN2 | c.827A>T p.N276I | Missense Mutation (SNP) | VAF 128/312 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZC3H8 | c.853A>G p.T285A | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF226 | c.1411G>T p.G471* | Nonsense Mutation (SNP) | VAF 174/435 reads (40%) | called by muse, mutect2, varscan2
- ZNF468 | c.55C>G p.Q19E | Missense Mutation (SNP) | VAF 283/646 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ZPBP | c.552C>A p.S184R | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ABCC11 | c.3066C>A p.I1022= | Silent (SNP) | VAF 68/212 reads (32%) | catalogued as COSV62326153; called by muse, mutect2, varscan2
- ACSS3 | c.1020T>A p.S340= | Silent (SNP) | VAF 78/378 reads (21%) | called by muse, mutect2, varscan2
- ADCY3 | c.330G>T p.V110= | Silent (SNP) | VAF 32/137 reads (23%) | catalogued as COSV53168768; called by muse, mutect2, varscan2
- AHNAK | c.17238A>T p.S5746= | Silent (SNP) | VAF 81/292 reads (28%) | called by muse, mutect2, varscan2
- AL445989.1 | c.333C>T p.G111= | Silent (SNP) | VAF 230/865 reads (27%) | called by muse, mutect2, varscan2
- ANO9 | c.516G>T p.R172= | Silent (SNP) | VAF 93/238 reads (39%) | called by muse, mutect2, varscan2
- ATP1A1 | c.162A>G p.K54= | Silent (SNP) | VAF 77/465 reads (17%) | called by muse, mutect2, varscan2
- CA7 | c.147G>A p.L49= | Silent (SNP) | VAF 263/686 reads (38%) | called by muse, mutect2, varscan2
- CENPF | c.8184C>T p.Y2728= | Silent (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.3636G>A p.T1212= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as rs767758345, COSV70493671; called by muse, mutect2, varscan2
- DAB2IP | c.2589C>T p.S863= (on ENST00000408936; = p.S835= on NM_032552.3) | Silent (SNP) | VAF 28/424 reads (7%) | catalogued as rs150585317; called by muse, mutect2
- DMD | c.8634G>A p.L2878= | Silent (SNP) | VAF 90/219 reads (41%) | called by muse, mutect2, varscan2
- ERICH3 | c.726G>T p.G242= | Silent (SNP) | VAF 62/242 reads (26%) | catalogued as COSV58608516; called by muse, mutect2, varscan2
- FCRL1 | c.645C>A p.P215= | Silent (SNP) | VAF 48/153 reads (31%) | called by muse, mutect2, varscan2
- FGFR3 | c.498G>T p.V166= | Silent (SNP) | VAF 108/279 reads (39%) | called by muse, mutect2, varscan2
- FOXRED1 | c.1437G>A p.K479= | Silent (SNP) | VAF 227/1112 reads (20%) | called by muse, mutect2, varscan2
- GLIS1 | c.1077G>T p.A359= | Silent (SNP) | VAF 54/177 reads (31%) | called by muse, mutect2, varscan2
- GLIS3 | c.687C>T p.Y229= | Silent (SNP) | VAF 17/150 reads (11%) | catalogued as rs1329895060; called by muse, mutect2, varscan2
- GLUD2 | c.396C>T p.I132= | Silent (SNP) | VAF 212/436 reads (49%) | catalogued as rs750276701; called by muse, mutect2, varscan2
- GOLGB1 | c.654G>T p.V218= | Silent (SNP) | VAF 50/187 reads (27%) | catalogued as COSV100511510; called by muse, mutect2, varscan2
- GRIK3 | c.2727C>A p.A909= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as COSV100901540; called by muse, mutect2, varscan2
- H4C5 | c.102C>T p.A34= | Silent (SNP) | VAF 121/311 reads (39%) | catalogued as rs774835775; called by muse, mutect2, varscan2
- KCNH2 | c.1113T>C p.T371= | Silent (SNP) | VAF 54/495 reads (11%) | called by muse, mutect2, varscan2
- KRTAP6-2 | c.144C>T p.F48= | Silent (SNP) | VAF 51/230 reads (22%) | catalogued as COSV58183177; called by muse, mutect2, varscan2
- LCE1C | c.45G>A p.K15= | Silent (SNP) | VAF 81/284 reads (29%) | called by muse, mutect2, varscan2
- LGALS13 | c.36G>T p.V12= | Silent (SNP) | VAF 973/1768 reads (55%) | called by muse, mutect2, varscan2
- NLRP11 | c.2415A>T p.L805= | Silent (SNP) | VAF 214/463 reads (46%) | called by muse, mutect2, varscan2
- NLRP12 | c.102C>A p.T34= | Silent (SNP) | VAF 231/466 reads (50%) | catalogued as COSV60748829; called by muse, mutect2, varscan2
- NTSR1 | c.570C>T p.S190= | Silent (SNP) | VAF 87/321 reads (27%) | catalogued as COSV65138523; called by muse, mutect2, varscan2
- OR4C16 | c.399C>A p.I133= | Silent (SNP) | VAF 39/150 reads (26%) | catalogued as rs1565052351, COSV58942873; called by muse, mutect2, varscan2
- OR4K14 | c.780G>T p.V260= | Silent (SNP) | VAF 79/393 reads (20%) | called by muse, mutect2, varscan2
- PCLO | c.10686G>A p.G3562= | Silent (SNP) | VAF 26/217 reads (12%) | called by muse, mutect2, varscan2
- PDCD4 | c.816A>G p.G272= | Silent (SNP) | VAF 114/420 reads (27%) | called by muse, mutect2, varscan2
- PGLS | c.669G>T p.P223= | Silent (SNP) | VAF 52/159 reads (33%) | called by muse, mutect2, varscan2
- PGM2 | c.141A>G p.L47= | Silent (SNP) | VAF 110/303 reads (36%) | catalogued as rs759390970; called by muse, mutect2, varscan2
- PIGK | c.492T>C p.H164= | Silent (SNP) | VAF 33/174 reads (19%) | called by muse, mutect2, varscan2
- PPARGC1B | c.2169C>G p.P723= | Silent (SNP) | VAF 90/240 reads (38%) | called by muse, mutect2, varscan2
- PTF1A | c.885C>A p.I295= | Silent (SNP) | VAF 214/631 reads (34%) | catalogued as COSV64735222; called by muse, mutect2, varscan2
- PTGES | c.51G>C p.L17= | Silent (SNP) | VAF 52/291 reads (18%) | called by muse, mutect2, varscan2
- RASSF10 | c.69C>T p.S23= | Silent (SNP) | VAF 67/207 reads (32%) | catalogued as rs1255292614; called by muse, mutect2, varscan2
- RGS12 | c.474G>T p.A158= | Silent (SNP) | VAF 115/293 reads (39%) | catalogued as rs753105172; called by muse, mutect2, varscan2
- RHCG | c.375C>A p.L125= | Silent (SNP) | VAF 10/32 reads (31%) | called by muse, varscan2
- RYR2 | c.4503C>T p.N1501= | Silent (SNP) | VAF 137/555 reads (25%) | catalogued as COSV63695939; called by muse, mutect2, varscan2
- SCTR | c.687C>T p.N229= | Silent (SNP) | VAF 67/235 reads (29%) | called by muse, mutect2, varscan2
- SERPINA7 | c.1026T>C p.N342= | Silent (SNP) | VAF 116/222 reads (52%) | called by muse, varscan2
- SLC27A6 | c.1116C>T p.N372= | Silent (SNP) | VAF 41/123 reads (33%) | called by muse, mutect2, varscan2
- SOX1 | c.99C>T p.G33= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs1054758083; called by muse, varscan2
- SOX10 | c.552C>A p.A184= | Silent (SNP) | VAF 195/441 reads (44%) | catalogued as COSV100703996; called by muse, mutect2, varscan2
- TBC1D13 | c.105C>T p.P35= | Silent (SNP) | VAF 32/91 reads (35%) | called by muse, mutect2, varscan2
- TLE3 | c.351G>A p.T117= | Silent (SNP) | VAF 51/328 reads (16%) | catalogued as rs377641820; called by muse, mutect2, varscan2
- TMEM52B | c.375G>T p.L125= (on ENST00000381923 / NM_001079815.1; = p.L105= on NM_153022.4) | Silent (SNP) | VAF 184/675 reads (27%) | called by muse, mutect2, varscan2
- TPO | c.2307G>T p.R769= | Silent (SNP) | VAF 140/783 reads (18%) | catalogued as rs766543408; called by muse, mutect2, varscan2
- TRABD2B | c.807A>T p.T269= | Silent (SNP) | VAF 86/249 reads (35%) | called by muse, mutect2, varscan2
- TRANK1 | c.5331G>T p.L1777= | Silent (SNP) | VAF 110/521 reads (21%) | called by muse, mutect2, varscan2
- TRIM29 | c.9T>C p.A3= | Silent (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2, varscan2
- TRPC3 | c.174G>C p.P58= | Silent (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- TTN | c.7533C>T p.D2511= (on ENST00000591111; = p.D2465= on NM_003319.4) | Silent (SNP) | VAF 54/280 reads (19%) | catalogued as rs878878455, COSV60131009; ClinVar: likely benign; called by muse, mutect2
- USP15 | c.414A>G p.L138= | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as rs547077774; called by muse, mutect2, varscan2
- VPS18 | c.450A>G p.A150= | Silent (SNP) | VAF 87/399 reads (22%) | called by muse, mutect2, varscan2
- ZYX | c.78C>T p.F26= | Silent (SNP) | VAF 36/327 reads (11%) | called by muse, mutect2, varscan2
- AC008758.3 | n.639A>T | RNA (SNP) | VAF 69/204 reads (34%) | called by muse, mutect2, varscan2
- ANTKMT | c.163-41G>T | Intron (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- ANXA6 | c.*16G>T | 3'UTR (SNP) | VAF 116/357 reads (32%) | called by muse, mutect2, varscan2
- ANXA8 | c.207+27del | Intron (DEL) | VAF 50/159 reads (31%) | called by mutect2, varscan2
- AP000769.5 | chr11:65498658 C>G | 5'Flank (SNP) | VAF 27/94 reads (29%) | called by muse, mutect2, varscan2
- ATP11B | c.-27C>T | 5'UTR (SNP) | VAF 50/150 reads (33%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.2178-40T>C | Intron (SNP) | VAF 71/244 reads (29%) | catalogued as rs764055169; called by muse, mutect2, varscan2
- CAMK2B | c.1597+614A>G | Intron (SNP) | VAF 33/104 reads (32%) | called by muse, mutect2, varscan2
- CCDC180 | c.2499-1686G>T | Intron (SNP) | VAF 68/160 reads (43%) | called by muse, mutect2, varscan2
- DNAH12 | c.5293+3198G>A | Intron (SNP) | VAF 88/300 reads (29%) | called by muse, mutect2, varscan2
- ESYT2 | c.223-11C>T | Intron (SNP) | VAF 9/17 reads (53%) | catalogued as rs1304254704; called by muse, mutect2, varscan2
- FAM183BP | n.250G>A | RNA (SNP) | VAF 7/23 reads (30%) | catalogued as rs898580508; called by muse, mutect2, varscan2
- FAM90A27P | n.586G>A | RNA (SNP) | VAF 128/232 reads (55%) | called by muse, mutect2, varscan2
- FRMD1 | chr6:168081512 C>T | 5'Flank (SNP) | VAF 50/130 reads (38%) | called by muse, mutect2, varscan2
- KCNQ2 | c.1763+1592G>T | Intron (SNP) | VAF 38/172 reads (22%) | called by muse, mutect2, varscan2
- KIAA0040 | c.-324A>T | 5'UTR (SNP) | VAF 86/302 reads (28%) | called by muse, mutect2, varscan2
- MGAT4FP | n.1111C>A | RNA (SNP) | VAF 15/128 reads (12%) | catalogued as rs1558026185; called by muse, mutect2, varscan2
- MTMR11 | c.-35C>T | 5'UTR (SNP) | VAF 101/437 reads (23%) | called by muse, mutect2, varscan2
- NCK1 | c.226+2337G>T | Intron (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141157473 C>A | 3'Flank (SNP) | VAF 1201/2017 reads (60%) | called by muse, mutect2, varscan2
- PIGK | c.987-7141G>T | Intron (SNP) | VAF 34/130 reads (26%) | called by mutect2, varscan2
- RABEP1 | c.2271+18A>G | Intron (SNP) | VAF 73/223 reads (33%) | catalogued as rs1383967223; called by muse, mutect2, varscan2
- RIMS2 | c.2084-943C>T | Intron (SNP) | VAF 90/326 reads (28%) | catalogued as rs529994606; called by muse, mutect2, varscan2
- SLC11A1 | c.393+123G>T | Intron (SNP) | VAF 132/745 reads (18%) | catalogued as COSV51915686; called by muse, mutect2, varscan2
- TMEM183B | n.150G>C | RNA (SNP) | VAF 126/546 reads (23%) | called by muse, mutect2, varscan2
- TSPY8 | c.-2G>T | 5'UTR (SNP) | VAF 162/560 reads (29%) | catalogued as rs773125040, COSV99819090, COSV99819093; called by muse, mutect2, varscan2
- TTC3P1 | n.5920G>A | RNA (SNP) | VAF 29/170 reads (17%) | called by muse, mutect2, varscan2
- WDR86 | chr7:151411298 C>A | 5'Flank (SNP) | VAF 23/287 reads (8%) | catalogued as rs1407202655; called by muse, mutect2
- XIST | n.10374G>T | RNA (SNP) | VAF 69/158 reads (44%) | called by muse, mutect2, varscan2
- ZBTB3 | c.-71G>T | 5'UTR (SNP) | VAF 78/350 reads (22%) | called by muse, mutect2
